Somatic mutation profile of tumor specimen ALCH-B2TN-TTP1-C (aliquot ALCH-B2TN-TTP1-C-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2TN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.0 years (22,280 days).
Specimen ALCH-B2TN-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f51b2eb-3784-4ffc-a933-050648f9cf01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2TN-NB1-A (Blood Derived Normal), aliquot ALCH-B2TN-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efdc7de5-53ba-457f-85b7-13e54acfed04

The open-access MAF lists 39 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Intron 5, Silent 4, 3'UTR 2, RNA 2, Frame Shift Del 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 228/952 reads (24%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 131/510 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.11525G>A p.R3842Q | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs770954138, COSV100003250, COSV52157432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDRT1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 29/353 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1178911326; called by muse, mutect2
- DTD1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 74/565 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.855); catalogued as rs1367995691; called by muse, mutect2, varscan2
- EXOC2 | c.2682G>A p.K894= | Splice Region (SNP) | VAF 18/292 reads (6%) | catalogued as rs755105209; called by muse, mutect2
- FBN2 | c.6680C>T p.T2227I | Missense Mutation (SNP) | VAF 48/852 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863223583; ClinVar: uncertain significance; called by muse, mutect2
- HSPA12B | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275253729, COSV99654257; called by muse, mutect2, varscan2
- NAV2 | c.3793C>G p.L1265V (on ENST00000396087 / NM_001244963.2; = p.L1242V on NM_145117.5) | Missense Mutation (SNP) | VAF 66/770 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV60660193; called by muse, mutect2
- NRSN1 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 20/327 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV65893796; called by muse, mutect2
- UBA6 | c.3146A>T p.H1049L | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs1236540360; called by muse, mutect2, varscan2
- AGTR2 | c.311A>C p.Y104S | Missense Mutation (SNP) | VAF 246/588 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ARL6IP6 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASPM | c.3071G>T p.S1024I | Missense Mutation (SNP) | VAF 21/598 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.426); called by muse, mutect2
- DNAH8 | c.10819G>A p.E3607K | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2
- DNAJC13 | c.176del p.P59Lfs*25 | Frame Shift Del (DEL) | VAF 44/222 reads (20%) | called by mutect2, pindel, varscan2
- ITPR2 | c.5603C>A p.T1868K | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- KCNA2 | c.777C>A p.D259E | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAPK9 | c.403A>G p.M135V | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2
- MPHOSPH8 | c.772G>T p.V258F | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); called by muse, mutect2
- PIEZO2 | c.3001C>G p.Q1001E | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- RHBDL1 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC22A23 | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.297); called by muse, mutect2
- SPTB | c.1271C>A p.A424D | Missense Mutation (SNP) | VAF 133/862 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM1 | c.1445C>G p.S482C | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2
- ZBTB44 | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- ATCAY | c.456C>T p.R152= | Silent (SNP) | VAF 51/364 reads (14%) | catalogued as rs766463929; called by muse, varscan2
- NDUFA10 | c.108G>A p.L36= | Silent (SNP) | VAF 14/426 reads (3%) | called by muse, mutect2
- PRICKLE3 | c.156G>A p.P52= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs1557101527; called by muse, mutect2
- RBSN | c.1281G>A p.V427= | Silent (SNP) | VAF 36/157 reads (23%) | called by muse, mutect2, varscan2
- AOAH | c.*17C>A | 3'UTR (SNP) | VAF 133/812 reads (16%) | called by muse, mutect2, varscan2
- ATIC | c.1503+694A>C | Intron (SNP) | VAF 39/368 reads (11%) | catalogued as rs984042158; called by muse, mutect2, varscan2
- FGFR4 | c.1057+173T>A | Intron (SNP) | VAF 85/608 reads (14%) | called by muse, mutect2, varscan2
- IDS | c.1007-194C>T | Intron (SNP) | VAF 81/268 reads (30%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5033G>C | Intron (SNP) | VAF 13/308 reads (4%) | catalogued as rs1324018496; called by muse, mutect2
- OR10AB1P | n.838T>C | RNA (SNP) | VAF 41/441 reads (9%) | called by muse, mutect2
- RBM23 | c.*5G>A | 3'UTR (SNP) | VAF 54/373 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.8830G>A | RNA (SNP) | VAF 35/189 reads (19%) | called by muse, mutect2, varscan2
- TPD52L1 | c.387-1655G>C | Intron (SNP) | VAF 21/436 reads (5%) | called by muse, mutect2
